Surgical pathology report (de-identified scan), TCGA case TCGA-05-4249, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-4249-01A (Primary Tumor).

Diagnosis:

2. and 3. Two-part resection material from the right lower lobe with a peripheral, well differentiated papillary, non-mucigenous adenocarcinoma measuring a good 50 mm and extending as far as the visceral pleura that is just tumor-free, a tumor-free bronchial resection level and subpleural areas of scarring as well as pleural residues of adhesion.

Tumor classification:

M-8140/3, G 1, pT 2, pN 0, pMX, stage I B. R 0.

Source: NCI Genomic Data Commons file 9074b6c8-e230-49b5-9e0c-a494556b60a5 (TCGA-05-4249.7E920317-D5C2-4160-9E2B-EF0101EB5A23.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).